Gene-level copy-number profile of tumor specimen C3L-07990-03 from CPTAC case C3L-07990, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 76.3 years (27,857 days).
Specimen C3L-07990-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3ef3ab54-0a98-4440-9826-00723c5ce101.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07990-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/b330b1ff-0c8e-4560-9dc6-e20d5189e3cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 205; copy number 2: 51,821; copy number 3: 6,330; copy number 4: 32.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene (within-gene range 0–2): U3.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
